Somatic mutation profile of tumor specimen MP2PRT-PAVZDB-TMP1-A (aliquot MP2PRT-PAVZDB-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVZDB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,222 days).
Specimen MP2PRT-PAVZDB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f75d45a-fbd3-47e7-a3a9-007935b403d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVZDB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVZDB-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abb36820-b7c9-47ff-88fd-0d6016cf0b9e

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.7499T>A p.I2500N | Missense Mutation (SNP) | VAF 13/462 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV63869065; called by muse, mutect2
- GAB2 | c.403G>C p.G135R (on ENST00000361507 / NM_080491.3; = p.G97R on NM_012296.3) | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs747769924; called by muse, mutect2, varscan2
- CDH9 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ENTPD8 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 48/516 reads (9%) | called by muse, mutect2
- KDM6A | c.3889_3890insGAAGGGATTT p.L1297Rfs*39 | Frame Shift Ins (INS) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- RAI1 | c.3245A>G p.D1082G | Missense Mutation (SNP) | VAF 16/631 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.202); called by muse, mutect2
- SF3B4 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 17/492 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); called by muse, mutect2
